Somatic mutation profile of tumor specimen C3N-02586-01 (aliquot CPT0147980010) from CPTAC case C3N-02586, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 74.0 years (27,040 days).
Specimen C3N-02586-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d98678d-3d88-48ed-b18b-fb9ebe6825e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02586-71 (Blood Derived Normal), aliquot CPT0148010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2efc90e-a5dc-4bfd-a3e0-dce5d79bcd4a

The open-access MAF lists 149 somatic variants for this specimen: 97 protein-altering or splice-affecting, 34 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 34, RNA 7, Intron 5, Nonsense Mutation 4, Frame Shift Del 4, 5'UTR 3, 5'Flank 2, Splice Region 2, 3'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 114/236 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs745425759, COSV52677009, COSV52679505, COSV53544033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS12 | c.3038G>T p.G1013V | Missense Mutation (SNP) | VAF 153/738 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.462); catalogued as COSV61273174; called by muse, mutect2, varscan2
- ADAMTS12 | c.2411C>A p.P804H | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710400; called by muse, mutect2, varscan2
- AKAP12 | c.1920C>A p.S640R | Missense Mutation (SNP) | VAF 121/248 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99482772; called by muse, mutect2, varscan2
- ANKRD1 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 156/417 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV65468656; called by muse, mutect2, varscan2
- ANKRD40 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 126/253 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as rs1358649196, COSV53333221; called by muse, mutect2, varscan2
- ANO4 | c.2230G>A p.E744K (on ENST00000392977 / NM_001286615.2; = p.E709K on NM_178826.4) | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100152393; called by muse, mutect2, varscan2
- CACNA2D1 | c.2949C>G p.F983L (on ENST00000356253 / NM_001366867.1; = p.F971L on NM_000722.4) | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV62371560, COSV62372187; called by muse, mutect2, varscan2
- COL5A3 | c.1540C>G p.R514G | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99319433; called by muse, mutect2, varscan2
- DCAF8L2 | c.1605T>A p.H535Q | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV70550005; called by muse, mutect2, varscan2
- DGKH | c.889A>G p.I297V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs779150570; called by muse, mutect2, varscan2
- DNAH11 | c.1649G>T p.R550M | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs762006113; called by muse, mutect2, varscan2
- EAF2 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV56544715; called by muse, mutect2, varscan2
- EBF1 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58197854; called by muse, varscan2
- EIF4E2 | c.429G>T p.L143F | Missense Mutation (SNP) | VAF 90/199 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as rs1462990064; called by muse, mutect2, varscan2
- ELAVL4 | c.67G>T p.G23* | Nonsense Mutation (SNP) | VAF 152/337 reads (45%) | catalogued as COSV63915952; called by muse, mutect2, varscan2
- FLG | c.5084C>A p.S1695* | Nonsense Mutation (SNP) | VAF 188/379 reads (50%) | catalogued as CM092260; called by muse, mutect2, varscan2
- GRIA4 | c.2318del p.L773* | Frame Shift Del (DEL) | VAF 107/247 reads (43%) | catalogued as COSV56916032; called by mutect2, pindel, varscan2
- ITGAX | c.3230C>T p.S1077F | Missense Mutation (SNP) | VAF 160/395 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV51642267; called by muse, mutect2, varscan2
- KCP | c.3152C>T p.T1051I (on ENST00000620378; = p.T1111I on NM_001366122.1) | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV99925934; called by muse, mutect2, varscan2
- KRIT1 | c.1582A>G p.I528V | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.881); catalogued as rs1449265064; called by muse, mutect2, varscan2
- KRT9 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 151/348 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs759755813; called by muse, mutect2, varscan2
- LPAR4 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101425152; called by muse, mutect2, varscan2
- MS4A14 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 148/294 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.146); catalogued as COSV55733705, COSV55734924; called by muse, mutect2, varscan2
- MYH2 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 173/357 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.081); catalogued as COSV55433810; called by muse, mutect2, varscan2
- PAK3 | c.652A>T p.T218S (on ENST00000262836 / NM_001324328.2; = p.T203S on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.468); catalogued as COSV53269814; called by muse, mutect2, varscan2
- PDLIM7 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs774710389, COSV100730313; called by muse, mutect2, varscan2
- PIWIL1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.175); catalogued as rs1164825118; called by muse, mutect2, varscan2
- RANBP6 | c.2918dup p.N973Kfs*19 | Frame Shift Ins (INS) | VAF 34/84 reads (40%) | catalogued as rs746880803; called by mutect2, varscan2
- RBP3 | c.1790C>A p.T597N | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs781867669; called by muse, mutect2, varscan2
- SEMA6A | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV99962664; called by muse, mutect2, varscan2
- SLC1A6 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 143/356 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55667543; called by muse, mutect2, varscan2
- TMEM255B | c.580C>G p.R194G | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs150929981; called by muse, mutect2, varscan2
- TNN | c.2551G>C p.V851L | Missense Mutation (SNP) | VAF 141/353 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV99511961; called by muse, mutect2, varscan2
- ADGRV1 | c.9010C>T p.Q3004* | Nonsense Mutation (SNP) | VAF 51/114 reads (45%) | called by muse, mutect2, varscan2
- ARL14EP | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 30/118 reads (25%) | called by muse, mutect2, varscan2
- CHD4 | c.1480A>G p.I494V (on ENST00000357008 / NM_001363606.2; = p.I507V on NM_001273.5) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNR1 | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2
- COL4A2 | c.3671C>A p.P1224H | Missense Mutation (SNP) | VAF 165/335 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CSMD1 | c.8278G>T p.V2760F (on ENST00000520002; = p.V2759F on NM_033225.6) | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CYP20A1 | c.299T>G p.F100C | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DISP3 | c.2326C>A p.L776M | Missense Mutation (SNP) | VAF 78/143 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ELAVL4 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 155/340 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EPB41L1 | c.1041G>C p.E347D | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAM149A | c.985C>G p.P329A (on ENST00000356371 / NM_001367768.2; = p.P38A on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM193A | c.1007del p.N336Tfs*4 | Frame Shift Del (DEL) | VAF 38/92 reads (41%) | called by mutect2, pindel, varscan2
- FOXB2 | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- GAGE2A | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 95/678 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- GLI3 | c.523A>T p.R175W | Missense Mutation (SNP) | VAF 156/614 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSG1 | c.713G>A p.R238K (on ENST00000651961 / NM_001080555.4; = p.E243= on NM_031289.5) | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- HMCN2 | c.11186G>C p.R3729T | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HMGXB3 | c.3725G>T p.G1242V (on ENST00000613459; = p.G996V on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/254 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- HNF4G | c.300C>A p.N100K (on ENST00000354370 / NM_001330561.2; = p.N147K on NM_004133.5) | Missense Mutation (SNP) | VAF 82/314 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.018); called by muse, varscan2
- IDUA | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- IGHV4-59 | c.326C>A p.T109K | Missense Mutation (SNP) | VAF 99/307 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- IL16 | c.2021A>T p.E674V | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IL23R | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 134/279 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIF6 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 177/378 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT73 | c.452G>C p.R151P | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LINC00305 | n.701-1G>T | Splice Site (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- LRRC9 | c.1148T>C p.L383S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRRTM4 | c.205A>T p.R69W | Missense Mutation (SNP) | VAF 159/308 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYPD6B | c.257A>G p.N86S (on ENST00000409029 / NM_001317004.1; = p.N110S on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, varscan2
- MLLT10 | c.949G>T p.G317W | Missense Mutation (SNP) | VAF 175/324 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MROH6 | c.1749_1751delinsA p.H583Qfs*156 | Frame Shift Del (DEL) | VAF 67/197 reads (34%) | called by pindel, varscan2*
- MUC4 | c.4420C>A p.L1474I | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- MUC5AC | c.16246G>T p.A5416S | Missense Mutation (SNP) | VAF 125/449 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- NKRF | c.2014C>A p.Q672K | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- PKHD1L1 | c.5317G>T p.G1773W | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRSS16 | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PSG2 | c.238A>T p.T80S | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- RANBP3L | c.572C>A p.A191E | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- RASSF9 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RELN | c.2583G>T p.M861I | Missense Mutation (SNP) | VAF 142/312 reads (46%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- RIMS2 | c.2654G>A p.R885K (on ENST00000666250 / NM_001348490.2; = p.R693K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- RIT2 | c.234G>A p.Q78= | Splice Region (SNP) | VAF 67/168 reads (40%) | called by muse, mutect2, varscan2
- RYR2 | c.13109C>G p.T4370R | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SGSM1 | c.994G>T p.V332F | Missense Mutation (SNP) | VAF 219/349 reads (63%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- SGSM3 | c.1525-7T>A | Splice Region (SNP) | VAF 127/228 reads (56%) | called by muse, mutect2, varscan2
- SMARCA2 | c.2416G>T p.G806C | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SPANXN1 | c.49T>A p.C17S | Missense Mutation (SNP) | VAF 140/289 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SPANXN3 | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- STX5 | c.624A>T p.R208S | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SYNE1 | c.22973G>T p.S7658I (on ENST00000367255 / NM_182961.4; = p.S7587I on NM_033071.3) | Missense Mutation (SNP) | VAF 147/290 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TACC2 | c.7461C>A p.D2487E (on ENST00000334433; = p.D565E on NM_006997.4) | Missense Mutation (SNP) | VAF 176/437 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- TDRD15 | c.3888del p.V1297Lfs*24 | Frame Shift Del (DEL) | VAF 48/120 reads (40%) | called by mutect2, pindel, varscan2
- TNFRSF10B | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 192/437 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPS1 | c.3478A>T p.N1160Y (on ENST00000220888 / NM_001330599.2; = p.N1173Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/471 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TRPV3 | c.2219C>A p.T740N | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TSHZ3 | c.660C>G p.S220R | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTBK1 | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- TTBK1 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC79 | c.6604A>G p.I2202V (on ENST00000393151 / NM_001346218.2; = p.I2025V on NM_020818.5) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- WDR19 | c.1526A>G p.N509S | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- WSCD2 | c.997A>G p.R333G | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF268 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF45 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- CARMIL3 | c.2055C>T p.A685= | Silent (SNP) | VAF 117/236 reads (50%) | catalogued as rs368927916; called by muse, mutect2, varscan2
- CCDC82 | c.237A>C p.P79= | Silent (SNP) | VAF 79/158 reads (50%) | called by muse, mutect2, varscan2
- CLCA4 | c.462C>T p.V154= | Silent (SNP) | VAF 76/142 reads (54%) | catalogued as COSV55369294; called by muse, mutect2, varscan2
- CSMD1 | c.10569T>C p.Y3523= (on ENST00000520002; = p.Y3522= on NM_033225.6) | Silent (SNP) | VAF 98/184 reads (53%) | called by muse, mutect2, varscan2
- FAM135B | c.1224C>A p.I408= | Silent (SNP) | VAF 54/193 reads (28%) | catalogued as rs1407590598, COSV52707267, COSV52748027; called by muse, mutect2, varscan2
- FAM47A | c.264T>A p.A88= | Silent (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- FKTN | c.735T>C p.S245= | Silent (SNP) | VAF 116/248 reads (47%) | catalogued as rs1455487670; called by muse, mutect2, varscan2
- IDO2 | c.543G>T p.G181= (on ENST00000389060; = p.G194= on NM_194294.2) | Silent (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
- IGSF9B | c.4269C>T p.L1423= | Silent (SNP) | VAF 50/235 reads (21%) | called by muse, mutect2, varscan2
- IRF2BPL | c.1407G>T p.G469= | Silent (SNP) | VAF 89/175 reads (51%) | called by muse, mutect2, varscan2
- KLHL14 | c.642G>C p.L214= | Silent (SNP) | VAF 148/352 reads (42%) | called by muse, mutect2, varscan2
- KRTAP26-1 | c.111A>T p.G37= | Silent (SNP) | VAF 56/139 reads (40%) | catalogued as COSV62129045; called by muse, mutect2, varscan2
- LRRC53 | c.756C>T p.T252= | Silent (SNP) | VAF 153/297 reads (52%) | catalogued as rs553610000; called by muse, mutect2, varscan2
- NLRP13 | c.2832G>T p.L944= | Silent (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- OR13H1 | c.360T>C p.Y120= | Silent (SNP) | VAF 51/201 reads (25%) | catalogued as rs376648153; called by muse, mutect2, varscan2
- OR5L1 | c.285A>G p.L95= | Silent (SNP) | VAF 138/321 reads (43%) | called by muse, mutect2, varscan2
- OR5L2 | c.435C>A p.T145= | Silent (SNP) | VAF 128/229 reads (56%) | called by muse, mutect2, varscan2
- OTULINL | c.510A>G p.K170= | Silent (SNP) | VAF 54/212 reads (25%) | called by muse, mutect2, varscan2
- P2RY10 | c.264C>A p.P88= | Silent (SNP) | VAF 95/188 reads (51%) | catalogued as COSV50680605, COSV99409459; called by muse, mutect2, varscan2
- PCDHGA10 | c.1722C>T p.D574= | Silent (SNP) | VAF 38/437 reads (9%) | called by muse, mutect2
- SDHC | c.255T>C p.F85= | Silent (SNP) | VAF 153/341 reads (45%) | catalogued as COSV61368395; called by muse, mutect2, varscan2
- SHISA6 | c.774T>A p.P258= | Silent (SNP) | VAF 92/178 reads (52%) | called by muse, mutect2, varscan2
- SLC12A5 | c.1197G>C p.S399= (on ENST00000454036 / NM_001134771.2; = p.S376= on NM_020708.5) | Silent (SNP) | VAF 82/197 reads (42%) | catalogued as COSV54801216, COSV99717016; called by muse, mutect2, varscan2
- SLITRK3 | c.1740C>A p.I580= | Silent (SNP) | VAF 61/289 reads (21%) | called by muse, mutect2, varscan2
- SMC1B | c.2121A>G p.G707= | Silent (SNP) | VAF 58/98 reads (59%) | called by muse, mutect2, varscan2
- SPATA2 | c.915C>T p.P305= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs767408253; called by muse, mutect2, varscan2
- SVEP1 | c.2704C>A p.R902= | Silent (SNP) | VAF 80/199 reads (40%) | catalogued as rs763911828, COSV100237540, COSV57028465; called by muse, mutect2, varscan2
- SYMPK | c.3384G>T p.P1128= | Silent (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- TFAP2B | c.1123C>A p.R375= | Silent (SNP) | VAF 203/385 reads (53%) | catalogued as COSV53829100; called by muse, mutect2, varscan2
- TMEM255B | c.579C>T p.Y193= | Silent (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- TOB1 | c.105T>A p.L35= | Silent (SNP) | VAF 15/190 reads (8%) | called by muse, mutect2
- TYW1B | c.147A>G p.T49= | Silent (SNP) | VAF 80/167 reads (48%) | called by muse, mutect2, varscan2
- ZNF808 | c.393A>G p.K131= | Silent (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- ZSCAN5C | c.1443G>A p.A481= | Silent (SNP) | VAF 59/117 reads (50%) | catalogued as rs779136794; called by muse, mutect2, varscan2
- AC136777.1 | n.277C>A | RNA (SNP) | VAF 136/305 reads (45%) | called by muse, mutect2, varscan2
- CCNYL2 | n.1027G>T | RNA (SNP) | VAF 36/140 reads (26%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*2250-792A>G | Intron (SNP) | VAF 242/481 reads (50%) | catalogued as rs965483152; called by muse, mutect2, varscan2
- DNAH14 | c.5585-926G>T | Intron (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- ENDOV | c.-26G>A | 5'UTR (SNP) | VAF 162/347 reads (47%) | catalogued as rs762529409, COSV60497242; called by muse, mutect2, varscan2
- LEMD2 | c.-10C>T | 5'UTR (SNP) | VAF 66/167 reads (40%) | catalogued as rs770338671, COSV99540371; called by muse, mutect2, varscan2
- MLIP | c.613-10844C>A | Intron (SNP) | VAF 87/199 reads (44%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.96G>C | RNA (SNP) | VAF 126/250 reads (50%) | catalogued as rs1289438683; called by muse, mutect2, varscan2
- NBPF22P | n.940G>T | RNA (SNP) | VAF 153/347 reads (44%) | called by muse, mutect2, varscan2
- PKD1L1 | c.-5A>T | 5'UTR (SNP) | VAF 81/357 reads (23%) | called by muse, mutect2, varscan2
- POTEM | c.811-1255C>T | Intron (SNP) | VAF 31/200 reads (16%) | called by mutect2, varscan2
- QPRT | chr16:29679131 G>T | 5'Flank (SNP) | VAF 66/143 reads (46%) | called by muse, mutect2, varscan2
- SHISA6 | chr17:11241415 G>T | 5'Flank (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- SNORD115-25 | n.80C>A | RNA (SNP) | VAF 103/245 reads (42%) | called by muse, mutect2, varscan2
- SSPOP | n.5609G>T | RNA (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- TOMM20 | c.*7A>C | 3'UTR (SNP) | VAF 70/152 reads (46%) | called by mutect2, varscan2
- WNK1 | c.2140-2268_2140-2265del | Intron (DEL) | VAF 33/72 reads (46%) | called by mutect2, pindel, varscan2
- ZFPM2 | n.261T>C | RNA (SNP) | VAF 91/299 reads (30%) | catalogued as rs1226285667; called by muse, mutect2, varscan2
